Somatic mutation profile of tumor specimen TARGET-30-PAPUWY-01A (aliquot TARGET-30-PAPUWY-01A-01D) from TARGET case TARGET-30-PAPUWY, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 5.4 years (1,955 days).
Specimen TARGET-30-PAPUWY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7aaada09-5dfc-4106-9299-663144136239.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAPUWY-10A (Blood Derived Normal), aliquot TARGET-30-PAPUWY-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bbc136b3-bd3c-4ce0-8967-91857430d6ff

The open-access MAF lists 34 somatic variants for this specimen: 26 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 22, Silent 8, Nonsense Mutation 2, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC098582.1 | c.279G>T p.E93D | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV52020782; called by muse, mutect2, varscan2
- AMELX | c.190C>A p.Q64K | Missense Mutation (SNP) | VAF 60/189 reads (32%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.926); catalogued as COSV61628752; called by muse, mutect2, varscan2
- AP4E1 | c.2767A>C p.N923H | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV55917478; called by muse, mutect2, varscan2
- ARFGEF3 | c.374C>A p.T125K | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as COSV52459247, COSV99294542; called by muse, mutect2, varscan2
- C8orf33 | c.235A>T p.N79Y | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV58895682; called by muse, mutect2, varscan2
- CA13 | c.694T>C p.C232R | Missense Mutation (SNP) | VAF 109/326 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.511); catalogued as rs1257824081, COSV58797995; called by muse, mutect2, varscan2
- CENPI | c.737C>A p.A246D | Missense Mutation (SNP) | VAF 133/379 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as COSV54503207; called by muse, mutect2, varscan2
- CLVS2 | c.475G>T p.V159F | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV51563779; called by muse, mutect2, varscan2
- CMYA5 | c.2222C>A p.S741* | Nonsense Mutation (SNP) | VAF 40/115 reads (35%) | catalogued as COSV71405134, COSV71406357; called by muse, mutect2, varscan2
- DGAT2L6 | c.652T>C p.Y218H | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs780650389, COSV60717929; called by muse, mutect2, varscan2
- FILIP1 | c.2806T>A p.F936I | Missense Mutation (SNP) | VAF 57/165 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); catalogued as COSV52731827; called by muse, mutect2, varscan2
- HEPH | c.1718G>T p.G573V (on ENST00000343002; = p.G306V on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100294643, COSV57965041; called by muse, mutect2, varscan2
- INTS5 | c.161A>G p.E54G | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.075); catalogued as COSV57951955; called by muse, mutect2, varscan2
- LRRC7 | c.293A>C p.E98A (on ENST00000651989 / NM_001370785.2; = p.E65A on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV50471919; called by muse, mutect2
- LURAP1 | c.224A>G p.K75R | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.184); catalogued as COSV64338216; called by muse, mutect2, varscan2
- LUZP2 | c.12C>G p.S4R | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.172); catalogued as COSV61206521; called by muse, mutect2, varscan2
- MNDA | c.524T>A p.L175Q | Missense Mutation (SNP) | VAF 55/159 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV63740982; called by muse, mutect2, varscan2
- OR10V1 | c.266G>T p.G89V | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.965); catalogued as COSV55698342; called by muse, mutect2, varscan2
- PAN2 | c.1265G>A p.R422Q | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as rs758421372, COSV57754229; called by muse, mutect2, varscan2
- REG3A | c.119del p.C40Ffs*53 | Frame Shift Del (DEL) | VAF 8/56 reads (14%) | catalogued as COSV59410912; called by pindel, varscan2
- SLC13A1 | c.1559C>A p.T520N | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV52012517; called by muse, mutect2, varscan2
- SLC45A3 | c.270G>A p.W90* | Nonsense Mutation (SNP) | VAF 21/58 reads (36%) | catalogued as COSV65655023; called by muse, mutect2, varscan2
- SORCS3 | c.1630-2A>C p.X544_splice | Splice Site (SNP) | VAF 21/58 reads (36%) | catalogued as COSV63812230, COSV63826192; called by muse, mutect2, varscan2
- UPRT | c.589G>C p.D197H | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64920269; called by muse, mutect2, varscan2
- USH2A | c.6358C>A p.L2120I | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.32); catalogued as COSV56379593; called by muse, mutect2, varscan2
- ZNF341 | c.519C>A p.S173R | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as COSV61008982, COSV61009922; called by muse, mutect2, varscan2
- CBX2 | c.840C>T p.A280= | Silent (SNP) | VAF 28/147 reads (19%) | catalogued as COSV53969289; called by muse, mutect2, varscan2
- ETFDH | c.510C>A p.G170= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV57015134; called by muse, mutect2, varscan2
- KDELR2 | c.384C>T p.S128= | Silent (SNP) | VAF 29/106 reads (27%) | catalogued as rs766520018, COSV51726760; called by muse, mutect2, varscan2
- LATS2 | c.3144C>T p.D1048= | Silent (SNP) | VAF 47/130 reads (36%) | catalogued as COSV66876393; called by muse, mutect2, varscan2
- PCDHB14 | c.1782C>A p.G594= | Silent (SNP) | VAF 23/121 reads (19%) | called by muse, mutect2, varscan2
- PDHA1 | c.1059C>A p.A353= | Silent (SNP) | VAF 52/145 reads (36%) | catalogued as COSV58831174; called by muse, mutect2, varscan2
- PPP1CA | c.975C>T p.S325= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as rs767893383, COSV57237107; called by muse, mutect2, varscan2
- TTI1 | c.72C>G p.T24= | Silent (SNP) | VAF 52/165 reads (32%) | catalogued as COSV65061827; called by muse, mutect2, varscan2
